TCGA case TCGA-93-A4JP — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Washington University - St. Louis. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/30f276a8-3a4b-4de8-aea0-7f605d100401

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 64 years; Vital status: Alive.

Diagnoses (2)
1. Papillary adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8260/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 64.7 years (23,620 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: TX; AJCC pathologic N: NX; AJCC pathologic M: M1b; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Days to treatment start: 17 days; Days to treatment end: 101 days; Treatment outcome: Partial Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Papillary adenocarcinoma, NOS). Age at diagnosis: 66.0 years (24,117 days); Days to diagnosis: 497 days (1.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS to Distant Site.

Follow-up (5 entries)
- Days to follow up: 269 days; Disease response: With Tumor.
- Day 497 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 497 days (1.4 years); Evidence of progression type: Convincing Image Source.
- Days to follow up: 578 days (1.6 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Post Adjuvant Therapy.
- ECOG performance status: 0; Timepoint: Preoperative.

Molecular and laboratory tests
- EGFR substitution: Positive; Amino-acid change: L861Q.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-93-A4JP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 450 mg.
  Slide TCGA-93-A4JP-01A-01-TSA: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 65; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 1.
- Samples TCGA-93-A4JP-01D, TCGA-93-A4JP-01E (2 with the same recorded description): Sample type: FFPE Scrolls; Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample TCGA-93-A4JP-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-93-A4JP-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Papillary Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor; Tobacco smoking history indicator: 1; Anatomic organ subdivision: R-Lower; KRAS gene analysis indicator: No; EGFR mutation status: Yes; EGFR mutation identified type: L861Q; Eml4 alk translocation status: No; Pulmonary function test indicator: No; Treatment outcome first course: Partial Remission/Response.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Partial Remission/Response; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No; Performance status timing: Post-Adjuvant Therapy.
- Follow-up form, New neoplasm event types: New tumor event type: Distant Metastasis.
- Follow-up form, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 578 days; disease-specific survival: no event (censored), 578 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 497 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-93-A4JP-01A-11D-A24O-01): tumor purity 0.27, ploidy 2.27, whole-genome doublings 0.
